CCDI case PBBJXV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/85e820f4-d3f0-47b3-b793-9e59712c58e9

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,403 days).

Biospecimens (3 samples)
- Sample 0DAN5W: Tissue type: Normal; Specimen type: Solid Tissue.
- Sample 0DAN62: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAN6N: Tissue type: Tumor; Specimen type: Solid Tissue.
